Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A7WC, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A7WC-01A (Primary Tumor).

[page 1 of 2]
---SURGICAL PATHOLOGY CONSULTATION--- (Accessor

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

- A. Soft tissue, left thigh, excision:
Leiomyosarcoma, high grade, 11.1 cm in maximum dimension, <0.1 cm from the anterior and posterior margins.
Areas highly suspicious for lymphovascular space invasion.
Previous biopsy site changes.
- B. Lymph nodes, left, excision:
No sarcoma in one lymph node (0/1).

Comment

Date reported: Pathologist (Electronic Signature)

HISTORY

None provided.

TISSUE SUBMITTED

- A. Lt thigh mass stitch proximal
B. Lt lymph node

FROZEN SECTION

- FS:
A. Lt thigh mass stitch proximal: FS: Sarcoma extends to within 1 cell layer of anterior margin.

G

A. Received fresh in a container labeled with the patient's name, hospital number and "Lt thigh mass stitch proximal" is a soft tissue mass with adjacent fascia and muscle with a stitch at one end indicating the proximal aspect. The surgeon is present for additional orientation and for gross margin assessment.
Specimen condition: Intact.
Type of procedure: Resection.
Overall size: 18.5 cm from proximal to distal, 13.5 cm from medial to lateral and 7.7 cm from anterior to posterior.
Weight: 880 grams.
Type of identifiable tissue present: Skeletal muscle and fibrous tissue.
Attached organs: None.
Tumor morphologic description: Upon sectioning, a well-circumscribed, multilobular mass is present with tan-pink, predominantly homogeneous cut surfaces. Focal areas of softening are present as well as cystic and hemorrhagic degeneration. While the majority of the mass is composed of confluent lobules, focal nodular areas are present.
Size: 11.1 x 11.0 x 6.7 cm.
Appearance and texture of cut surfaces: Firm, predominantly homogeneous tan-pink and lobulated.
Estimate percent necrosis: <5%.
Previous biopsy site/scar: The areas of necrosis and cystic degeneration may represent prior needle biopsy site; however, no definitive biopsy site is present. No scar is identified.
Involvement/invasion of major structures: none identified.
Presence of satellite nodules away from the main mass: Not identified.
Lymph nodes: Please see additional section.
Margins: The anterior and posterior (against bone) margins are closely approximated measuring <0.1 cm grossly. These areas are firmly adherent to the mass and are not freely movable. A representative section from each of these areas is submitted for frozen section. Additional margins include medial margin 0.1 cm, proximal margin 0.8 cm, distal margin 2.9 cm, lateral margin >1.0 cm.
Photograph: None taken.
Tissue saved for special studies: This tissue is consented and a portion of the tumor is provided for a study.
Ink identifiers by pathologist: Medial and lateral margin=orange; proximal margin=blue; distal margin=green; deep (adjacent to bone)=black; anterior (muscle and fascia)=orange.
Blocks submitted: A1, frozen section remnant; A2, lateral margin, representative section; A3-A4, medial margin, representative section with closest tumor; A5-A7, representative sections of tumor and posterior margin; A8, representative sections of additional anterior margin; A9, representative section of tumor with proximal margin; A10, representative sections of distal margin (no tumor in close approximation grossly); A11-A13, additional representative sections of tumor including cystic, hemorrhagic and degenerated areas.
B. Received free floating in formalin in a container labeled with the patient's name, hospital number and "Lt lymph node" is an aggregate of yellow-tan soft tissue measuring 4.0 x 3.2 x 1.2 cm. A lymph node search is performed and one lymph node is identified measuring 4.0 x 3.0 x 1.2 cm. The specimen is serially sectioned and submitted entirely in B1-B4.

ICD-0-3
Leiomyosarcoma NOS
8890/3
Late Thigh NOS
049.2
JW 10/10/13

[page 2 of 2]
MICROSCOPIC

Tumor microscopic description: Sections of tumor show bundles of cells intersecting at right angles, a high mitotic rate, and significant cytologic atypia.

Histologic type: Leiomyosarcoma.

Histologic grade: High.

Mitotic rate (per 10 hpf @ 40X): >50.

Extent of necrosis: Slight.

Vascular invasion: Identified.

Inflammatory infiltrate: None identified.

Minimal distance(s) to resection margins: <0.1 cm anteriorly, <0.1 cm posteriorly, <0.3 cm medially, >1.0 cm laterally.

Lymph nodes: See other section.

DEFINITIONS

Pathologic Primary Tumor (T)

- ___ TX Primary tumor cannot be assessed
- ___ T0 No evidence of primary tumor
- ___ T1 Tumor 5 cm or less in greatest dimension
- ___ T1a Superficial tumor (1)
- ___ T1b Deep tumor
- ___ T2 Tumor more than 5 cm in greatest dimension
- ___ T2a Superficial tumor (1)
- XX T2b Deep tumor

Regional Lymph Nodes (N)

- ___ NX Regional lymph nodes cannot be assessed
- XX N0 No regional lymph node metastasis
- ___ N1 Regional lymph node metastasis

The pathologic stage based on available pathologic material is: T2b N0.

The optimal tissue block for molecular studies on neoplasm is A13.

B. Sections show fibroadipose tissue with focal lymphoid aggregates with no evidence of metastasis.

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

---SURGICAL PATHOLOGY CONSULTATION--- (Order #

and Collection Information

Result History

---SURGICAL PATHOLOGY CONSULTATION--- (Order

Order Result History Report

Result Entered By:

Lab Information

HUPA Discrepancy		✓

Source: NCI Genomic Data Commons file 8df65b84-9463-4871-b76f-4790bcdb6392 (TCGA-X6-A7WC.7BABE13D-9D34-4689-9097-5726A16A6A60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).